Gene-level copy-number profile of tumor specimen TCGA-A2-A0D1-01A from TCGA case TCGA-A2-A0D1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.9 years (28,084 days).
Specimen TCGA-A2-A0D1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.bca3ec5f-f504-4f47-9359-6576d0ca164a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0D1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/199c9a54-e844-477c-8ab4-d9556f070acf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 132; copy number 2: 11,905; copy number 3: 3,912; copy number 4: 39,521; copy number 5: 244; copy number 6: 1,518; copy number 7: 48; copy number 8: 420; copy number 9: 446; copy number 10: 168; copy number 11: 1,059; copy number 12: 52; copy number 13: 232; copy number 14: 9; copy number 16: 22; copy number 18: 16; copy number 19: 5; copy number 25: 19; copy number 26: 5; copy number 31: 6; copy number 44: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0D1-01A-11D-A036-01): tumor purity 0.76, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,115 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:7,968,796–8,094,272, 1 gene, copy number 31 (within-gene range 4–31): GLCCI1.
- chr7:8,113,184–10,239,863, 19 genes, copy number 18–31: ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3.
- chr7:10,451,311–10,476,878, 2 genes, copy number 18: HSPA8P8, AC009945.1.
- chr7:19,918,981–20,415,754, 10 genes, copy number 9: AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1.
- chr7:21,900,899–21,945,903, 1 gene, copy number 12: CDCA7L.
- chr7:55,019,017–56,882,146, 76 genes, copy number 44 (broad region; genes not listed).
- chr8:33,338,867–34,039,104, 19 genes, copy number 10 (within-gene range 7–10): RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1.
- chr8:37,326,575–38,382,272, 44 genes, copy number 11 (within-gene range 7–11): AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1.
- chr8:38,699,274–40,897,833, 35 genes, copy number 11 (within-gene range 2–11): AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4.
- chr8:42,271,302–145,066,685, 1,582 genes, copy number 9–14 (within-gene range 8–14) (broad region; genes not listed).
- chr12:119,667,864–120,641,591, 44 genes, copy number 9: PRKAB1, CIT, AC002563.1, MIR1178, RPL35AP30, BICDL1, Metazoa_SRP, AC004812.1, RAB35, AC004812.2, GCN1, MIR4498, RPLP0, PXN-AS1, PXN, AC004263.2, AC004263.1, RPS20P31, NME2P1, RNU4-2, RNU4-1, SIRT4, RNU6-1088P, PLA2G1B, MSI1, RPS27P25, AC003982.1, COX6A1, AL021546.1, TRIAP1, GATC, RPL31P52, SRSF9, DYNLL1, NRAV, AC063943.1, COQ5, Y_RNA, RPL29P24, RNF10, AC063943.2, POP5, RPL11P5, AC125616.1.
- chr16:48,718,083–49,275,579, 7 genes, copy number 13–19 (within-gene range 8–19): KLF8P1, RNU6-257P, AC023827.1, MTND4LP25, AC044798.3, AC044798.1, AC044798.2.
- chr17:28,018,770–28,357,527, 22 genes, copy number 16: AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22, AC061975.8, AC061975.7, PYY2, ERVE-1, AC061975.6, PPY2P, AC061975.2, AC061975.4, AC061975.1, AC061975.5, AC061975.3, KRT18P55, TMEM97, IFT20, TNFAIP1, POLDIP2.
- chr17:29,073,521–29,078,857, 1 gene, copy number 12: TIAF1.
- chr17:36,591,879–36,726,346, 5 genes, copy number 26: DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1.
- chr17:39,461,486–40,381,838, 48 genes, copy number 11–25 (within-gene range 7–25): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2.
- chr17:48,133,442–48,430,275, 1 gene, copy number 10 (within-gene range 6–10): SKAP1.
- chr17:48,294,335–50,910,774, 148 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr17:63,972,920–64,975,576, 50 genes, copy number 12: AC127029.2, PRR29-AS1, PRR29, ICAM2, ERN1, AC005803.1, SNHG25, SNORD104, AC025362.1, SNORA50C, TEX2, RPL31P57, PECAM1, Y_RNA, AC234063.1, MILR1, POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9, LRRC37A3, RN7SL404P, AC103810.6, AC103810.7, AC103810.2, AC103810.5, RDM1P4, AC103810.1, AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1, AMZ2P1.

Autosomal genes at a single copy (total copy number 1): 132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
